Surgical pathology report (de-identified scan), TCGA case TCGA-86-8674, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8674-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]		
Case ID	ID	Excision date
[REDACTED]	[REDACTED]	[REDACTED]

[page 2 of 3]
Gross Description	Microscopic Description	Diagnosis Details
Lobe of the lung 12x4x8 cm with gray tumor of 4 cm in diameter.	Papillary adenocarcinoma of the lung, G-2. One of two examined paratracheal lymph node demonstrated metastasis. Four examined subcarinal lymph nodes demonstrated sinus histiocytosis. Three examined bronchopulmonal lymph nodes demonstrated sinus histiocytosis.	Tumor Features: -1, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 3 of 3]
Comments	Formatted Path Report
In the original paper surgery name is pneumectomy, but macroscopic description sais "Lobe of the lung with tumor".	LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 0 x 0 x 4 cm Histologic type: Papillary adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 1/9 positive for metastasis (Paratracheal 1/2, Subcarinal, broncho-pulmonary. 0/7) Lymphatic invasion: Not specified Venous invasion: Present Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- middle

Source: NCI Genomic Data Commons file 452d395c-7e3c-4111-ae2a-b2aecdc02b9f (TCGA-86-8674.463CD118-45EF-4E2F-ACA3-39CE953DCB09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).